Somatic mutation profile of tumor specimen TCGA-ZG-A9LN-01A (aliquot TCGA-ZG-A9LN-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9LN, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.6 years (21,050 days).
Specimen TCGA-ZG-A9LN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0867f9ec-b231-438b-825c-f5f6950061d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9LN-10A (Blood Derived Normal), aliquot TCGA-ZG-A9LN-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c19b5e8c-5e0c-46e1-8366-998a10617716

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD79A | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99701930; called by muse, mutect2, varscan2
- CDC25B | c.1117T>A p.S373T (on ENST00000245960 / NM_021873.3; = p.S359T on NM_004358.4) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); catalogued as COSV99847626; called by muse, mutect2, varscan2
- CRACD | c.3079C>T p.Q1027* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99948687; called by muse, mutect2, varscan2
- DDX11 | c.242C>G p.T81S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99299038; called by muse, mutect2, varscan2
- FPR3 | c.504T>A p.S168R | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV100200608; called by muse, mutect2, varscan2
- GBF1 | c.5146G>T p.E1716* (on ENST00000369983 / NM_001377137.1; = p.E1715* on NM_004193.3) | Nonsense Mutation (SNP) | VAF 40/284 reads (14%) | catalogued as rs1361707601, COSV100890344; called by muse, mutect2, varscan2
- HMG20B | c.146A>T p.E49V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99502977; called by muse, mutect2
- ILF2 | c.806+2T>A p.X269_splice | Splice Site (SNP) | VAF 35/247 reads (14%) | catalogued as COSV100721861; called by muse, mutect2, varscan2
- ITGAL | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs755499977, COSV63324384; called by muse, mutect2, varscan2
- KLK3 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100385929; called by muse, mutect2, varscan2
- NCKAP1L | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53203197; called by muse, mutect2, varscan2
- PCDHGA7 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.022); catalogued as COSV99532055; called by muse, mutect2, varscan2
- PHC1 | c.2157G>T p.M719I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV101418523; called by muse, mutect2, varscan2
- PPT2 | c.435C>A p.D145E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as COSV99278240; called by muse, mutect2, varscan2
- PRPF4B | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100528056; called by muse, mutect2, varscan2
- RAPGEF4 | c.2557C>G p.H853D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99909898; called by muse, mutect2, varscan2
- RMI1 | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100366069; called by muse, mutect2, varscan2
- ULK4 | c.1691A>G p.N564S | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1450896043, COSV100090680; called by muse, mutect2, varscan2
- YKT6 | c.475T>A p.S159T | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV99790500; called by muse, mutect2, varscan2
- ZNF157 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV100998455; called by muse, mutect2, varscan2
- ZNF536 | c.2045C>T p.S682L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100834762, COSV62829766; called by muse, mutect2
- MMP11 | c.771del p.Y257* | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- ATG9A | c.1812C>G p.L604= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV54700104; called by muse, mutect2, varscan2
- CNBD1 | c.288C>T p.G96= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV101572848; called by muse, mutect2
- COL5A1 | c.582C>T p.S194= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs563191799, COSV100879265; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD3 | c.33A>T p.A11= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV99826307; called by muse, mutect2, varscan2
- EFEMP1 | c.684C>T p.C228= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs139930646; called by muse, mutect2, varscan2
- IGKV2D-29 | c.270C>T p.S90= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs750263848, COSV101534363; called by muse, mutect2, varscan2
- IQSEC1 | c.339C>A p.S113= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, varscan2
- LFNG | c.1029C>G p.A343= (on ENST00000222725 / NM_001040167.2; = p.A214= on NM_002304.2) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs749597262, COSV99761681; called by muse, mutect2, varscan2
- PGM1 | c.1104G>A p.A368= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as rs776558188, COSV64301256; called by muse, mutect2
- SPCS1 | c.399A>G p.P133= (on ENST00000233025; = p.P66= on NM_014041.5) | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as rs754676127, COSV51778038; called by muse, mutect2, varscan2
